Somatic mutation profile of tumor specimen TCGA-HV-A7OP-01A (aliquot TCGA-HV-A7OP-01A-11D-A33T-08) from TCGA case TCGA-HV-A7OP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 72.1 years (26,322 days).
Specimen TCGA-HV-A7OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c91fc005-dc17-491d-84e4-0ed50f5678fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A7OP-10A (Blood Derived Normal), aliquot TCGA-HV-A7OP-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8ade4c3-6733-4cce-9f30-5f7be5556356

The open-access MAF lists 103 somatic variants for this specimen: 67 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 33, Frame Shift Del 3, Nonsense Mutation 2, 3'Flank 2, In Frame Ins 1, Splice Site 1, 5'Flank 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 173/210 reads (82%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/82 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4471G>A p.A1491T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV101329932, COSV70049329; called by muse, mutect2, varscan2
- ADAMTS9 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898769; called by muse, mutect2
- AFF1 | c.667del p.R223Gfs*27 | Frame Shift Del (DEL) | VAF 413/924 reads (45%) | catalogued as COSV57121208; called by mutect2, pindel, varscan2
- AKAP9 | c.5393C>A p.S1798Y (on ENST00000359028; = p.S1766Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/596 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100661929; called by muse, mutect2, varscan2
- ALG10B | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 181/664 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100439792; called by muse, mutect2, varscan2
- ANK3 | c.5740C>T p.R1914W | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1274185754, COSV99778439; called by muse, mutect2
- ARSD | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 116/136 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs151213601, COSV54198929; called by muse, mutect2, varscan2
- ATP8A2 | c.2365A>G p.K789E | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99680137; called by muse, mutect2
- BRINP3 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 347/1413 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100818380; called by muse, mutect2, varscan2
- C10orf90 | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 212/701 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99503097, COSV99503141; called by muse, mutect2, varscan2
- C6orf118 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 272/606 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1291677088, COSV100024112; called by muse, mutect2, varscan2
- CES3 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 144/247 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100309806; called by muse, mutect2, varscan2
- CHD6 | c.5588A>G p.H1863R | Missense Mutation (SNP) | VAF 189/419 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV100950567; called by muse, mutect2, varscan2
- COL6A6 | c.3193T>A p.F1065I | Missense Mutation (SNP) | VAF 160/357 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV100649828; called by muse, mutect2, varscan2
- CYP27B1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 233/282 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV99141509; called by muse, mutect2, varscan2
- CYP2F1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 37/519 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100462540; called by muse, mutect2
- DGKB | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV99336610; called by muse, mutect2
- DNAAF5 | c.1684C>G p.H562D | Missense Mutation (SNP) | VAF 312/801 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV99859266; called by muse, mutect2, varscan2
- DPEP2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 64/802 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1452721094, COSV52056283; called by muse, mutect2
- DST | c.6218G>A p.C2073Y | Missense Mutation (SNP) | VAF 203/488 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99751340; called by muse, mutect2, varscan2
- ECM1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 62/557 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs199951855, COSV100681657; called by muse, mutect2, varscan2
- FAM135B | c.4028C>A p.A1343E | Missense Mutation (SNP) | VAF 68/1059 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99419207; called by muse, mutect2
- FXR1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1306954007, COSV59762123; called by muse, mutect2
- GEMIN2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs775884653; called by muse, mutect2
- GMPR | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 329/763 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs370707259, COSV99439774; called by muse, mutect2, varscan2
- GRINA | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV100507233; called by muse, mutect2, varscan2
- HECTD2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 36/1140 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV99978151; called by muse, mutect2
- HS3ST3B1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs759162056, COSV100714451; called by muse, varscan2
- HSPA12A | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 29/732 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs782613611, COSV100979712; called by muse, mutect2
- INA | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 372/1112 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs778675936, COSV100878571; called by muse, varscan2
- KCNQ5 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 58/970 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100571331; called by muse, mutect2
- KIAA1217 | c.2972T>C p.L991P | Missense Mutation (SNP) | VAF 34/963 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100286217; called by muse, mutect2
- KIF9 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 78/539 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646376; called by muse, mutect2, varscan2
- L3MBTL2 | c.1484T>C p.I495T | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99345666; called by muse, mutect2, varscan2
- MAPRE3 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 25/476 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1230161170, COSV99251537; called by muse, mutect2
- MCPH1 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV100765271; called by muse, mutect2, varscan2
- MVP | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100651484, COSV100651700; called by muse, mutect2
- NOL4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 157/608 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs757148536, COSV52338009; called by muse, mutect2, varscan2
- NOL8 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV62634161; called by muse, mutect2, varscan2
- OR10K2 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 199/829 reads (24%) | catalogued as COSV100149390; called by muse, mutect2, varscan2
- PCDHB14 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 127/154 reads (82%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.031); catalogued as COSV99505557; called by muse, mutect2, varscan2
- PIK3CA | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 179/436 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV55894472, COSV55994731, COSV99834082; called by muse, mutect2, varscan2
- PIK3CG | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771251636, COSV100782548; called by muse, mutect2
- PIP4K2A | c.493-1G>A p.X165_splice | Splice Site (SNP) | VAF 88/315 reads (28%) | catalogued as COSV100114364; called by muse, mutect2, varscan2
- PKHD1 | c.8936G>A p.R2979Q | Missense Mutation (SNP) | VAF 230/571 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs761651295, COSV100581179; called by muse, mutect2, varscan2
- PLEKHG1 | c.3146_3147del p.E1049Vfs*31 | Frame Shift Del (DEL) | VAF 178/581 reads (31%) | catalogued as rs749773056; called by pindel, varscan2
- PODN | c.992C>G p.T331S (on ENST00000395871; = p.T283S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV100439347; called by muse, mutect2, varscan2
- PSD | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 194/780 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs774485946, COSV50042597; called by muse, mutect2, varscan2
- PTPN13 | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs558463399, COSV100364060; called by muse, mutect2, varscan2
- RMDN3 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 366/439 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99539859; called by muse, mutect2, varscan2
- RSPO4 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99448812; called by muse, mutect2, varscan2
- SIN3A | c.3664G>A p.V1222M | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99145226; called by muse, mutect2, varscan2
- SMAD3 | c.1277A>T p.*426Lext*6 | Nonstop Mutation (SNP) | VAF 94/117 reads (80%) | catalogued as COSV100528709; called by muse, mutect2, varscan2
- SPTBN1 | c.1715T>G p.L572R | Missense Mutation (SNP) | VAF 99/259 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100441835; called by muse, mutect2, varscan2
- TCF7 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389768; called by muse, mutect2
- TOP2B | c.1967G>A p.R656H (on ENST00000264331 / NM_001330700.2; = p.R651H on NM_001068.3) | Missense Mutation (SNP) | VAF 360/832 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs757502615, COSV51968590; called by muse, mutect2, varscan2
- TPP2 | c.2490A>C p.Q830H | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as COSV101060172; called by muse, mutect2, varscan2
- TTN | c.32185C>T p.P10729S (on ENST00000591111; = p.P9802S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/604 reads (6%) | PolyPhen possibly damaging (0.701); catalogued as rs775021272, COSV100595057; called by muse, mutect2
- VPS13A | c.7325G>A p.G2442D | Missense Mutation (SNP) | VAF 64/848 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100652187; called by muse, mutect2
- ZNF398 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 229/516 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1051940846, COSV100246814; called by muse, mutect2, varscan2
- CCDC198 | c.727dup p.M243Nfs*7 | Frame Shift Ins (INS) | VAF 71/115 reads (62%) | called by mutect2, pindel, varscan2
- MMRN1 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- PRKD1 | c.2442del p.I816Sfs*7 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- PTP4A2 | c.101_103dup p.L34_K35insI | In Frame Ins (INS) | VAF 69/94 reads (73%) | called by mutect2, varscan2
- RGPD2 | c.4273G>A p.D1425N | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AGAP2 | c.3027C>T p.R1009= (on ENST00000547588 / NM_001122772.2; = p.R653= on NM_014770.4) | Silent (SNP) | VAF 63/72 reads (88%) | catalogued as COSV57730418; called by muse, mutect2, varscan2
- ARSB | c.396C>G p.L132= | Silent (SNP) | VAF 17/664 reads (3%) | catalogued as rs940744532; called by muse, mutect2
- B3GLCT | c.948T>A p.I316= | Silent (SNP) | VAF 30/348 reads (9%) | catalogued as COSV100587137; called by muse, mutect2
- CDH23 | c.3363C>A p.I1121= | Silent (SNP) | VAF 99/165 reads (60%) | catalogued as COSV56491888; called by muse, mutect2, varscan2
- COL12A1 | c.2679C>T p.D893= | Silent (SNP) | VAF 72/918 reads (8%) | catalogued as rs747852589, COSV100485419, COSV59390063; called by muse, mutect2
- CPA6 | c.324C>T p.L108= | Silent (SNP) | VAF 335/809 reads (41%) | catalogued as COSV52737257, COSV99912557; called by mutect2, varscan2
- DCLK2 | c.501G>A p.V167= | Silent (SNP) | VAF 27/215 reads (13%) | catalogued as COSV99651421; called by muse, mutect2, varscan2
- EGLN3 | c.129C>T p.V43= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as COSV99164288; called by muse, mutect2, varscan2
- F9 | c.966C>T p.D322= | Silent (SNP) | VAF 325/362 reads (90%) | catalogued as rs373107855, COSV99496345; called by muse, mutect2, varscan2
- FAM135A | c.4005A>T p.S1335= (on ENST00000370479 / NM_001351599.1; = p.S1122= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 170/419 reads (41%) | catalogued as COSV99525253; called by muse, mutect2, varscan2
- FAM209A | c.156C>T p.T52= | Silent (SNP) | VAF 46/602 reads (8%) | catalogued as COSV99711129; called by muse, mutect2
- GRIA4 | c.108C>T p.N36= | Silent (SNP) | VAF 22/389 reads (6%) | catalogued as rs1183373527, COSV99229101; called by muse, mutect2
- HPD | c.708C>T p.I236= | Silent (SNP) | VAF 111/469 reads (24%) | catalogued as COSV100000028; called by muse, mutect2, varscan2
- IFIT1 | c.348T>A p.T116= | Silent (SNP) | VAF 120/388 reads (31%) | catalogued as COSV100878666; called by muse, mutect2, varscan2
- MRC2 | c.1971G>A p.P657= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs201376256, COSV57638555; called by muse, mutect2, varscan2
- NPR2 | c.1044G>T p.L348= | Silent (SNP) | VAF 58/1042 reads (6%) | catalogued as COSV100709312; called by muse, mutect2
- OR5L1 | c.96T>A p.L32= | Silent (SNP) | VAF 94/1078 reads (9%) | catalogued as COSV100449921; called by muse, mutect2
- OR6F1 | c.720G>A p.T240= | Silent (SNP) | VAF 92/1070 reads (9%) | catalogued as rs376931741; called by muse, mutect2
- PCDH10 | c.1911G>A p.E637= | Silent (SNP) | VAF 34/240 reads (14%) | catalogued as COSV99992773, COSV99993026; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 397/494 reads (80%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- POLR3B | c.1554G>A p.L518= | Silent (SNP) | VAF 68/413 reads (16%) | called by muse, mutect2, varscan2
- RSPRY1 | c.459T>C p.D153= | Silent (SNP) | VAF 99/948 reads (10%) | catalogued as COSV101070930; called by muse, mutect2, varscan2
- RXFP3 | c.51C>T p.G17= | Silent (SNP) | VAF 70/1044 reads (7%) | catalogued as COSV100347312; called by muse, mutect2
- SH2D4B | c.414C>T p.I138= | Silent (SNP) | VAF 69/553 reads (12%) | catalogued as COSV100213555; called by muse, mutect2, varscan2
- SLC22A23 | c.1698G>C p.V566= | Silent (SNP) | VAF 21/272 reads (8%) | catalogued as COSV100978111; called by muse, mutect2
- SLITRK6 | c.513T>A p.A171= | Silent (SNP) | VAF 287/999 reads (29%) | catalogued as COSV101233181; called by muse, mutect2, varscan2
- TCERG1L | c.1290G>A p.E430= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs1462694504, COSV100893871; called by muse, mutect2
- THBD | c.1080C>T p.G360= | Silent (SNP) | VAF 73/457 reads (16%) | catalogued as COSV65702065; called by muse, mutect2, varscan2
- TMEM255A | c.306G>A p.A102= | Silent (SNP) | VAF 80/94 reads (85%) | catalogued as rs782414647, COSV59029268; called by muse, mutect2, varscan2
- TRPS1 | c.2248C>T p.L750= (on ENST00000220888 / NM_001330599.2; = p.L763= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 170/1275 reads (13%) | catalogued as COSV99628541; called by muse, mutect2, varscan2
- TTN | c.41823C>A p.G13941= (on ENST00000591111; = p.G6517= on NM_003319.4) | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as rs759938870, COSV60200148; ClinVar: likely benign; called by muse, mutect2, varscan2
- WNT3A | c.489G>T p.G163= | Silent (SNP) | VAF 18/593 reads (3%) | catalogued as COSV99468824; called by muse, mutect2
- WNT5A | c.549C>T p.G183= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as COSV99224723; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445764 C>T | 3'Flank (SNP) | VAF 59/595 reads (10%) | catalogued as rs746181650; called by muse, mutect2, varscan2
- RARB | chr3:25596473 C>T | 3'Flank (SNP) | VAF 308/709 reads (43%) | catalogued as COSV51968704, COSV99979203; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853025 C>G | 5'Flank (SNP) | VAF 35/372 reads (9%) | called by muse, mutect2
